Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8M4, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8M4-01A (Primary Tumor).

[page 1 of 2]
Operative Procedure:

Thymectomy

Pre-Operative Diagnosis:

As below

Post-Operative Diagnosis:

As below

Specimen Received:

Mediastinal mass

Final Pathologic Diagnosis:

Mediastinum, mass, excision:

Thymoma (WHO type B2) with microscopic invasion of adipose tissue (slide 8).

- Tumor separated from inked margin by less than 0.2 mm (ink is directly upon the fibrous capsule of the tumor); the margin; nonetheless transection of the tumor is not present.

- Maximal tumor dimension equals 8.5 cm.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

Received is a single fixative-filled container labeled with the patient's name, and additionally labeled "mediastinal mass." Received is a pink-tan firm mass with attached adipose tissue, 14.0 x 7.5 x 5.0 cm in aggregate. The mass is 8.5 x 5.0 x 4.5 cm in maximal dimension and is covered by a pink-gray, glistening surface. Sectioning reveals a pink-tan, lobulated, firm cut surface with occasional intervening white septa. The mass is well-circumscribed without areas of hemorrhage or necrosis. The attached adipose tissue is 12.5 x 11.5 x 2.0 cm. No masses, nodules or lymph node candidates are identified. Representative sections of the tumor mass are submitted in cassettes 1-10.

Microscopic Description:

Sections show sheets and lobules of epithelial cells admixed with lymphocytes, separated by intervening fibrous bands. Portions of the tumor are surrounded by an apparent fibrous capsule; however, tumor cells penetrate this capsule and extend into the adjacent adipose tissue.

The tumor is positive for cytokeratins CAM5.2 and AE1/AE3. These results confirm the epithelial nature of the tumor. Control stains reacted appropriately.

Interpretation

Flow cytometric analysis of mediastinal mass demonstrates predominantly T cells and few polyclonal B cells. Note - viability is only 54%. Suggest morphologic correlation.

Results-Comments

Percent

Percent

CD2	(Total T-Cell)	85	CD19	(Pan-B)	<1
CD3	(Pan T-Cell)	6	CD5	(T-Cell)	81

ICD O-3

Thymoma, type B2, malignant
8584/3

Date: Mediastinum NOS
C38.3

Q1 6/10/14

[page 2 of 2]
CD7 (T-Cell)	96	CD19+/CD5+	<1
CD23 (B-Cell)	3	CD25 (IL-2 receptor)	<1
HLA-Dr	2	CD19+/Kappa+	<1
CD22 (B-Cell)	1	CD19+/Lambda+	<1
CD11c (Mono/Macrophage)	1	CD4	64
CD22+/CD11c+	<1	CD8	19
CD20 (B-Cell)	<1	CD1a	78
CD10 (CALLA)	40	cyto CD3	80
Tdt	8		

Viability : 54

Morphologic review of cytospin demonstrates numerous stripped cells with few small mature lymphocytes.

Surgical Pathology Report

Taken: - DOB: (Age: Gender: M Race: White

IHC/Path Discrepancy		☒
Case in File	☒	
Reviewed Initials	SC	

Source: NCI Genomic Data Commons file e15c9ebb-a0cc-41d9-9fa4-e3be8d67a8e4 (TCGA-X7-A8M4.0BD281B7-6AF5-4036-BC76-783933BE25D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).